HCMI case HCM-BROD-1098-C91 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7d03e209-ad89-461e-b5f9-f7dc88a2684c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1943; Vital status: Dead; Days to death: 1,394 days (3.8 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Prolymphocytic leukemia, T-cell type: ICD-O-3 morphology code: 9834/3; ICD-10 code: C91.6; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 73.2 years (26,723 days); Tumor grade: GX; Prior malignancy: yes; Prior treatment: No.
   Pathology details: Lymph nodes positive: 1; Lymph nodes tested: 1; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Days to treatment start: 1,306 days (3.6 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Busulfan + Fludarabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,307 days (3.6 years); Days to treatment end: 1,310 days (3.6 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (1 entry)
- Days to follow up: 1,394 days (3.8 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- ATM substitution (Sequencing, NOS): Positive.
- DNMT3A substitution (Sequencing, NOS): Positive.
- GNAS mutation, nos: Positive; Amino-acid change: R201S.
- NOTCH1 loss (Sequencing, NOS): Positive.
- RAD21 gain (Sequencing, NOS): Positive.
- Lactate Dehydrogenase 171.
- Leukocytes 15.9 ×10³/µL.
- Hemoglobin 15.1 g/dL.
- Hematocrit 45%.
- Platelets 262 ×10³/µL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 98 kg; Height: 174 cm; BMI: 32.4.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (1 sample)
- Sample HCM-BROD-1098-C91-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
